Somatic mutation profile of tumor specimen 0DNRUU from CCDI case PBCBUS, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 19.4 years (7,097 days).
Specimen 0DNRUU: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5f7593fd-1785-41fd-8256-53e29b62c438.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DNRTR (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e6e8e228-7330-4b25-b0ff-01091aae69fc

The open-access MAF lists 13 somatic variants for this specimen: 9 protein-altering or splice-affecting, 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, 3'UTR 2, Silent 1, Frame Shift Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CLEC18B | c.1039G>A p.A347T | Missense Mutation (SNP) | VAF 192/1299 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1284795747, COSV100376069; called by muse, mutect2, varscan2
- KAT6B | c.1927A>T p.M643L | Missense Mutation (SNP) | VAF 404/1024 reads (39%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0.006); catalogued as rs778899637; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LAMA5 | c.3175G>A p.A1059T | Missense Mutation (SNP) | VAF 294/773 reads (38%) | SIFT tolerated (0.59); PolyPhen benign (0.013); catalogued as rs776498744, COSV104386500; called by muse, mutect2, varscan2
- PFKL | c.2201G>A p.R734H | Missense Mutation (SNP) | VAF 279/682 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV57394844; called by muse, mutect2, varscan2
- ZFX | c.2291G>A p.R764Q | Missense Mutation (SNP) | VAF 371/814 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV58447480; called by muse, mutect2, varscan2
- ZNFX1 | c.1321C>T p.R441C | Missense Mutation (SNP) | VAF 345/1033 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as rs758850504, COSV65573750, COSV65574803; called by muse, mutect2, varscan2
- ANKRD18A | c.2135A>C p.E712A | Missense Mutation (SNP) | VAF 368/442 reads (83%) | SIFT tolerated (0.05); PolyPhen benign (0.027); called by muse, varscan2
- OR2AK2 | c.709G>T p.A237S | Missense Mutation (SNP) | VAF 405/917 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- PBRM1 | c.1448_1451del p.K483Rfs*16 | Frame Shift Del (DEL) | VAF 384/516 reads (74%) | called by pindel, varscan2
- NTNG1 | c.156G>A p.P52= | Silent (SNP) | VAF 201/1151 reads (17%) | catalogued as rs774773683, COSV53965758; called by muse, mutect2, varscan2
- AMACR | c.*665G>C | 3'UTR (SNP) | VAF 14/337 reads (4%) | called by muse, mutect2
- CAPN12 | c.1816-53C>G | Intron (SNP) | VAF 188/415 reads (45%) | called by muse, mutect2, varscan2
- MMEL1 | c.*23G>A | 3'UTR (SNP) | VAF 73/287 reads (25%) | catalogued as rs751893119; called by muse, mutect2, varscan2
